CCDI case PBBUXZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d6ec60ea-14ea-4176-af98-99fb3e16f448

Demographics
Sex at birth: male.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,922 days).

Biospecimens (3 samples)
- Sample 0DI5EE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI5EU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI5FK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
